Somatic mutation profile of tumor specimen TCGA-QK-A6IH-01A (aliquot TCGA-QK-A6IH-01A-11D-A31L-08) from TCGA case TCGA-QK-A6IH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.5 years (23,936 days).
Specimen TCGA-QK-A6IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76208080-16dc-4c3a-a0c5-fd5ecd129c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6IH-10A (Blood Derived Normal), aliquot TCGA-QK-A6IH-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ada341f8-ba29-4707-b28d-14986ce50d03

The open-access MAF lists 77 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Nonsense Mutation 3, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 106/277 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50461395, COSV50462411; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 24/39 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375267880; called by muse, mutect2, varscan2
- AKAP17A | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100001883; called by muse, mutect2, varscan2
- AL031777.2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 36/94 reads (38%) | catalogued as rs779876735, COSV61912207; called by muse, mutect2, varscan2
- AMIGO1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as COSV63990505; called by muse, mutect2, varscan2
- BTN2A1 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100438383; called by muse, mutect2, varscan2
- CACYBP | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs780696971, COSV62880510; called by muse, mutect2, varscan2
- CAD | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as rs575934358, COSV99254431; called by muse, mutect2, varscan2
- CFAP206 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV51532449; called by muse, mutect2, varscan2
- CIT | c.1526C>G p.T509S | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV99948424; called by muse, mutect2
- CSNK1E | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs773976199, COSV100724967; called by muse, mutect2, varscan2
- DCHS1 | c.7844C>T p.T2615I | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100197180; called by muse, mutect2, varscan2
- DDX3X | c.995G>C p.R332T (on ENST00000399959; = p.R333T on NM_001356.5) | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101302342; called by muse, mutect2, varscan2
- DOCK5 | c.3340C>G p.L1114V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99376082; called by muse, mutect2, varscan2
- ETS2 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.999); catalogued as rs915550106, COSV100711182; called by muse, mutect2, varscan2
- FERD3L | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 81/129 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99284726; called by muse, mutect2, varscan2
- FFAR1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199506594, COSV50050607; called by muse, mutect2, varscan2
- FLNB | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 49/70 reads (70%) | catalogued as COSV99911831; called by muse, mutect2, varscan2
- GBP5 | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372467199, COSV100599978; called by muse, mutect2, varscan2
- HDAC2 | c.1423dup p.T475Nfs*27 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | catalogued as rs1352627084; called by mutect2, pindel, varscan2
- IFI44L | c.1358G>C p.*453Sext*5 | Nonstop Mutation (SNP) | VAF 52/148 reads (35%) | catalogued as COSV100654878; called by muse, mutect2, varscan2
- IFT172 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.407); catalogued as rs763117647, COSV53129814; called by muse, mutect2, varscan2
- KDM5B | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs750789070, COSV52503696; called by muse, mutect2, varscan2
- KNL1 | c.1390G>A p.E464K (on ENST00000346991 / NM_170589.5; = p.E438K on NM_144508.5) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100705959; called by muse, mutect2, varscan2
- L3MBTL3 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV100695738; called by muse, varscan2
- LDLR | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs758248798, COSV99369565; called by muse, mutect2, varscan2
- LIPN | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV101356209; called by muse, mutect2, varscan2
- LRRN1 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV100076045, COSV100076178; called by muse, mutect2, varscan2
- MAVS | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100816245; called by muse, mutect2, varscan2
- MEP1B | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328658; called by muse, mutect2, varscan2
- METTL3 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1228535300, COSV52967973; called by muse, mutect2, varscan2
- NCF4 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs761060692, COSV50623764; called by muse, mutect2, varscan2
- NCKIPSD | c.671A>T p.D224V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs988590978, COSV53660785, COSV99583716; called by muse, mutect2, varscan2
- NEK5 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs957673200, COSV62880811; called by muse, mutect2, varscan2
- NXPH1 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339581; called by muse, mutect2, varscan2
- OR5D14 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100162133, COSV59455863; called by muse, mutect2, varscan2
- OTUD7B | c.2078C>G p.P693R | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); catalogued as rs782557628, COSV100967359; called by muse, mutect2, varscan2
- PHIP | c.4805A>C p.K1602T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.954); catalogued as COSV99243447; called by muse, mutect2, varscan2
- RIOK2 | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV99299776; called by muse, mutect2, varscan2
- RNF103 | c.1525A>G p.I509V | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as rs765917255, COSV99409937; called by muse, mutect2, varscan2
- RYR2 | c.5144C>T p.A1715V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100768081; called by muse, mutect2
- SCAMP5 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs368193195; called by muse, mutect2, varscan2
- SEMA7A | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV99984550; called by muse, mutect2, varscan2
- SENP2 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV99957563; called by muse, mutect2, varscan2
- SEPTIN2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs751366308, COSV100764911; called by muse, mutect2, varscan2
- SEZ6L | c.2812G>C p.E938Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV50663372, COSV50691041, COSV99961121; called by muse, mutect2, varscan2
- SHROOM3 | c.2010G>C p.E670D | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV99933563, COSV99935050; called by muse, mutect2, varscan2
- SLC10A4 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.825); catalogued as COSV99906773; called by muse, mutect2, varscan2
- SLC9A2 | c.1853C>T p.S618F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52135184; called by muse, mutect2, varscan2
- SLCO3A1 | c.1421A>C p.N474T | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV100574925; called by muse, mutect2, varscan2
- TMEM132E | c.1315G>A p.E439K (on ENST00000321639; = p.E529K on NM_001304438.2) | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV100395951; called by muse, mutect2, varscan2
- UBN2 | c.3554G>T p.R1185M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99943630; called by muse, mutect2, varscan2
- UNC5C | c.2571T>A p.D857E | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101497786; called by muse, mutect2, varscan2
- WDR62 | c.1236G>A p.V412= | Splice Region (SNP) | VAF 46/95 reads (48%) | catalogued as COSV99543194; called by muse, mutect2, varscan2
- WDR72 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771955935, COSV64741479; called by muse, mutect2, varscan2
- XIRP2 | c.2390C>A p.T797K (on ENST00000628543; = p.T972K on NM_152381.6) | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as COSV99738692; called by muse, mutect2, varscan2
- ZBTB22 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs147840428, COSV56472041; called by muse, mutect2, varscan2
- ZNF43 | c.2090A>G p.K697R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.959); catalogued as COSV100731692; called by muse, mutect2, varscan2
- PCDHGB5 | c.2021G>T p.R674L | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PKD1 | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2
- ADCY8 | c.285C>T p.G95= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99650810; called by muse, mutect2, varscan2
- CCDC8 | c.645G>C p.P215= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100281887; called by muse, mutect2, varscan2
- CYP2C9 | c.1173G>C p.L391= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs750386209, COSV53249772; called by muse, mutect2
- CYP3A7 | c.885C>G p.L295= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100312560; called by muse, mutect2, varscan2
- DAPK1 | c.3678G>A p.T1226= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs202069940, COSV100801053, COSV63786054; called by muse, mutect2, varscan2
- FER1L6 | c.2025C>T p.C675= | Silent (SNP) | VAF 41/229 reads (18%) | catalogued as COSV101205474; called by muse, mutect2, varscan2
- GRM1 | c.588T>C p.T196= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV51117494, COSV51140435; called by muse, mutect2, varscan2
- JCHAIN | c.315A>T p.I105= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99636286; called by muse, varscan2
- MYO6 | c.1605T>G p.L535= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV100889279; called by muse, mutect2, varscan2
- OR2G3 | c.771C>T p.Y257= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs769678031, COSV60681547, COSV60681730; called by muse, mutect2, varscan2
- OSGIN2 | c.1068C>G p.V356= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV99858074; called by muse, mutect2, varscan2
- SCRT1 | c.39C>T p.D13= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs781913285, COSV59781352; called by muse, mutect2, varscan2
- SEL1L3 | c.498C>A p.I166= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99339494; called by muse, mutect2, varscan2
- SPACA4 | c.165G>T p.P55= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV54368757, COSV99613798; called by muse, mutect2, varscan2
- TMEM151A | c.732C>T p.S244= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV59173602; called by muse, mutect2
- CIRBP | c.-7+533C>T | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
